Somatic mutation profile of tumor specimen MMRF_2050_1_BM_CD138pos (aliquot MMRF_2050_1_BM_CD138pos_T1_KHS5U_L08808) from MMRF case MMRF_2050, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.5 years (28,675 days).
Specimen MMRF_2050_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 349c6da0-6538-43c2-9df8-ef3a832e352e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2050_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2050_1_PB_WBC_C3_KHS5U_L08812; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89b99d83-1eed-4c02-ba81-24290f311db2

The open-access MAF lists 122 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 31, Intron 18, Silent 12, RNA 6, 5'UTR 5, 5'Flank 3, Splice Site 2, Nonsense Mutation 2, 3'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370689695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP9B | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs778501286, COSV100304243; called by muse, mutect2, varscan2
- FAM47A | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as rs568669965, COSV100650039; called by mutect2, varscan2
- FBXO5 | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262836073; called by muse, mutect2, varscan2
- IGHV4-34 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs768900759; called by muse, mutect2
- IGKV4-1 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs145449257; called by muse, mutect2, varscan2
- KBTBD13 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1341273094; called by muse, mutect2
- KCNV2 | c.941C>A p.T314K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66055515; called by muse, mutect2, varscan2
- MXRA5 | c.6748_6750del p.E2250del | In Frame Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs1383388854; called by pindel, varscan2
- MYBL2 | c.2089C>T p.L697F | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53827662; called by muse, mutect2, varscan2
- NUMA1 | c.5405G>A p.R1802H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.78); catalogued as rs146335857, COSV52621970; called by muse, mutect2, varscan2
- PAPSS1 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99492498; called by muse, mutect2, varscan2
- POLG2 | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 61/145 reads (42%) | catalogued as COSV56747798; called by muse, mutect2, varscan2
- SCRIB | c.2216G>A p.G739D | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554636743; called by muse, mutect2, varscan2
- ABCD2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CDH20 | c.2344C>A p.P782T | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CITED2 | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CKAP5 | c.850T>A p.F284I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by mutect2, varscan2
- COG6 | c.1627dup p.Y543Lfs*5 | Frame Shift Ins (INS) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- DCAF12L1 | c.1014G>T p.Q338H | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DEPDC1B | c.1012T>C p.C338R | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNMBP | c.2651A>G p.E884G | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DSC3 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- FCGBP | c.10594G>C p.D3532H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FOCAD | c.2650C>T p.H884Y | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HMCN1 | c.15320-1G>T p.X5107_splice | Splice Site (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.235T>G p.F79V | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, varscan2
- IGHV2-70D | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- IGHV3-33 | c.146_149delinsAGCA p.S49_S50delinsKH | Missense Mutation (ONP) | VAF 32/115 reads (28%) | called by pindel, varscan2*
- IGHV3-33 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.433); called by muse, varscan2
- ILRUN | c.742G>C p.D248H (on ENST00000374023 / NM_024294.4; = p.D182H on NM_022758.6) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KNDC1 | c.3358G>A p.D1120N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MICALL1 | c.1021A>T p.N341Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, varscan2
- NUTM1 | c.2600T>C p.L867P | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PIGB | c.1487C>G p.T496S | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PLCB1 | c.1819T>G p.S607A | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PPP2CB | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- PSMD10 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RASGRF1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- SLC16A7 | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SOCS7 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SP5 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TOP2A | c.478+2T>C p.X160_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.206+3A>T | Splice Region (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- TSEN34 | c.388G>C p.A130P | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- USP36 | c.2170del p.T724Pfs*173 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- BOD1L2 | c.27C>T p.S9= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV73996899; called by muse, mutect2, varscan2
- CDH22 | c.402G>A p.T134= | Silent (SNP) | VAF 48/127 reads (38%) | catalogued as rs752285113; called by muse, mutect2, varscan2
- FLT4 | c.1092C>T p.P364= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs746150032, COSV56098715; called by muse, mutect2, varscan2
- ICA1 | c.936G>A p.K312= | Silent (SNP) | VAF 13/56 reads (23%) | called by muse, varscan2
- KCTD15 | c.552C>T p.S184= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as rs376850099; called by muse, mutect2, varscan2
- KLF4 | c.402G>A p.S134= | Silent (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- MED12L | c.5277A>G p.K1759= | Silent (SNP) | VAF 96/165 reads (58%) | called by muse, varscan2
- NEB | c.2172A>G p.Q724= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV51428560; called by muse, mutect2, varscan2
- NR2C2 | c.741C>T p.N247= (on ENST00000393102; = p.N266= on NM_003298.5) | Silent (SNP) | VAF 47/76 reads (62%) | called by muse, varscan2
- PKD1L1 | c.5916C>T p.A1972= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs924737504; called by muse, mutect2, varscan2
- SERPINE1 | c.1011T>C p.P337= | Silent (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- ZMYND15 | c.1932C>T p.S644= (on ENST00000433935 / NM_001136046.3; = p.S605= on NM_032265.2) | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- AC008060.1 | n.354C>A | RNA (SNP) | VAF 18/31 reads (58%) | catalogued as rs183325711; called by muse, mutect2, varscan2
- ADAM33 | c.2241-10C>T | Intron (SNP) | VAF 28/65 reads (43%) | catalogued as rs531336690; called by muse, mutect2, varscan2
- AFF2 | c.*6648T>C | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- AL355390.1 | n.510G>C | RNA (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- AL772337.1 | n.858-100A>G | Intron (SNP) | VAF 9/27 reads (33%) | catalogued as rs887889079; called by muse, mutect2, varscan2
- AP3B2 | c.360+1924G>T | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021260 C>G | 5'Flank (SNP) | VAF 50/117 reads (43%) | catalogued as COSV55846296; called by muse, mutect2, varscan2
- BCL7A | chr12:122021492 C>T | 5'Flank (SNP) | VAF 34/88 reads (39%) | catalogued as COSV55846308, COSV55846472; called by muse, mutect2, varscan2
- BMP6 | c.*716_*723del | 3'UTR (DEL) | VAF 10/65 reads (15%) | called by mutect2, varscan2
- C10orf90 | c.1720-130T>C | Intron (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- C6orf136 | c.72+312G>A | Intron (SNP) | VAF 6/127 reads (5%) | catalogued as COSV99528279; called by muse, mutect2
- C8orf44-SGK3 | c.-481-1896G>A | Intron (SNP) | VAF 49/114 reads (43%) | called by muse, mutect2, varscan2
- CCDC170 | c.*2220T>C | 3'UTR (SNP) | VAF 18/24 reads (75%) | called by muse, mutect2, varscan2
- CCNYL2 | n.1237G>C | RNA (SNP) | VAF 56/139 reads (40%) | called by muse, mutect2, varscan2
- CD58 | c.743+141A>C | Intron (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- CLOCK | c.*1263G>C | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- CPEB1 | c.371-66T>A | Intron (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- CTNND2 | c.*367C>G | 3'UTR (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- DENND1A | c.-26C>T | 5'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- ENKUR | c.*466T>C | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- EPB41L4B | c.*1269T>G | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- FAM241A | c.*244T>A | 3'UTR (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- FIGN | c.*4666T>C | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, varscan2
- FMN1 | c.2161+633A>C | Intron (SNP) | VAF 75/185 reads (41%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.112G>T | RNA (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- G3BP2 | c.*1790G>C | 3'UTR (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- GPR75 | c.-199G>A | 5'UTR (SNP) | VAF 31/50 reads (62%) | catalogued as rs781014651; called by muse, mutect2, varscan2
- H2BC21 | c.*62T>A | 3'UTR (SNP) | VAF 23/89 reads (26%) | catalogued as COSV58613401; called by muse, mutect2, varscan2
- HDGF | c.-228C>T | 5'UTR (SNP) | VAF 31/49 reads (63%) | called by muse, mutect2, varscan2
- HMGN1 | c.127-169T>G | Intron (SNP) | VAF 3/10 reads (30%) | catalogued as rs1385952238; called by muse, mutect2
- INSM1 | c.*840G>A | 3'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as rs1352607962; called by muse, mutect2
- KCNIP4 | c.61+251207G>T | Intron (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- LINC01630 | n.1432T>G | RNA (SNP) | VAF 24/50 reads (48%) | catalogued as rs1260238121; called by muse, mutect2, varscan2
- LONRF2 | c.*5051G>A | 3'UTR (SNP) | VAF 5/101 reads (5%) | catalogued as rs1184883622; called by muse, mutect2
- LZTS3 | c.*237T>C | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- MICAL2 | c.-13C>T | 5'UTR (SNP) | VAF 17/27 reads (63%) | catalogued as rs373036219; called by muse, mutect2, varscan2
- MIER3 | c.*151G>A | 3'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- MYADML | n.855C>T | RNA (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- NCOA3 | c.*835A>T | 3'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as rs1252012997, COSV100507196; called by muse, mutect2, varscan2
- NRXN1 | c.832+2556C>A | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- PACRGL | c.609+2661G>A | Intron (SNP) | VAF 6/121 reads (5%) | called by muse, mutect2
- PAPPA | c.*4766A>C | 3'UTR (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- PHACTR1 | c.1447+353G>A | Intron (SNP) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- PPP1R18 | chr6:30686797 C>T | 5'Flank (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- REEP2 | c.*1131G>A | 3'UTR (SNP) | VAF 6/46 reads (13%) | catalogued as rs1219164870; called by muse, mutect2, varscan2
- RNF169 | c.*2289G>A | 3'UTR (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- RPE | c.*429T>G | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- SDCBP2 | c.733-74C>T | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-36519C>T | Intron (SNP) | VAF 7/20 reads (35%) | catalogued as rs1037273896; called by muse, mutect2, varscan2
- SLC25A53 | c.*2468G>A | 3'UTR (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- SLC35B3 | chr6:8411612 A>G | 3'Flank (SNP) | VAF 83/160 reads (52%) | called by muse, varscan2
- SLCO1A2 | c.*2663T>C | 3'UTR (SNP) | VAF 12/34 reads (35%) | catalogued as rs1182491728; called by muse, mutect2, varscan2
- SPPL2B | c.956+572C>T | Intron (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- SSR1 | c.*4322A>G | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- SSR3 | c.*1697A>G | 3'UTR (SNP) | VAF 7/39 reads (18%) | catalogued as rs1129105; called by muse, mutect2, varscan2
- TM4SF1 | c.*170T>A | 3'UTR (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- TMEM151B | c.*879C>A | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- TMEM164 | c.*4202T>G | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- UBE2F | c.*1108G>A | 3'UTR (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- UNC119B | c.*3555A>G | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- VSTM2A | c.*1507A>C | 3'UTR (SNP) | VAF 54/78 reads (69%) | called by muse, mutect2, varscan2
- ZNF660 | c.*4200T>C | 3'UTR (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- ZNRF3 | c.-136C>A | 5'UTR (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.568+1148T>C | Intron (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
